Somatic mutation profile of tumor specimen C3L-00458-54 (aliquot CPT0054750002) from CPTAC case C3L-00458, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 39.2 years (14,333 days).
Specimen C3L-00458-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1be1f839-e3ab-4be2-8b7b-1b8047a6b7a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00458-51 (Buccal Cell Normal), aliquot CPT0054800005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5dab36cd-f0fb-4400-8dc0-c48ef7dbc5ee

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZNF717 | c.2218_2219insCA p.C740Sfs*155 | Frame Shift Ins (INS) | VAF 8/54 reads (15%) | catalogued as rs77245454, COSV68858011; called by mutect2, pindel
- P4HA1 | c.1468_1469insT p.A490Vfs*8 | Frame Shift Ins (INS) | VAF 8/112 reads (7%) | called by mutect2, pindel
- TOPBP1 | c.345_349delinsACAAA p.S115_E117delinsRQK | Missense Mutation (ONP) | VAF 6/42 reads (14%) | called by muse*, pindel
